Somatic mutation profile of tumor specimen MP2PRT-PAUEDJ-TBP1-A (aliquot MP2PRT-PAUEDJ-TBP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUEDJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,607 days).
Specimen MP2PRT-PAUEDJ-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2de19cc3-5dd0-4184-b8dd-ef9abc4052a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUEDJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUEDJ-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccaab18c-336b-4a49-828c-b477796056ca

The open-access MAF lists 40 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 8, Nonsense Mutation 2, 3'Flank 1, Intron 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC5 | c.3476C>T p.S1159L | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765292844; called by muse, mutect2, varscan2
- APOA4 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 250/544 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as rs767254316, COSV63360044; called by muse, mutect2, varscan2
- CELF3 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 169/380 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV51882366; called by muse, mutect2, varscan2
- DNHD1 | c.12991G>A p.E4331K | Missense Mutation (SNP) | VAF 33/401 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0.01); catalogued as rs767015100; called by muse, mutect2
- FILIP1L | c.1120G>C p.E374Q (on ENST00000354552 / NM_182909.3; = p.E134Q on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs1194685298; called by muse, mutect2
- GUCY1A2 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 198/394 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs1400948872, COSV56480894; called by muse, mutect2, varscan2
- NR4A2 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 155/309 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV59894326; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 168/399 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF157 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 39/301 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs1218575285; called by muse, mutect2, varscan2
- SCARA5 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 71/649 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.137); catalogued as rs1219972109, COSV57280639; called by muse, mutect2, varscan2
- STK31 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 98/204 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV63456160; called by muse, mutect2, varscan2
- XPO5 | c.2368G>C p.E790Q | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54829095; called by muse, mutect2
- ATP8B3 | c.1751C>G p.P584R | Missense Mutation (SNP) | VAF 136/322 reads (42%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- CPXM1 | c.1703G>A p.W568* | Nonsense Mutation (SNP) | VAF 145/337 reads (43%) | called by muse, mutect2, varscan2
- FAM160B1 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2
- FOXN4 | c.1288C>G p.L430V | Missense Mutation (SNP) | VAF 117/248 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- H1-3 | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 97/216 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406863 CTACCCCATTCACAGTGTTACAA>GTCCGTTGAG | Missense Mutation (DEL) | VAF 47/50 reads (94%) | called by pindel, varscan2*
- MLF1 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 26/297 reads (9%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.831); called by muse, mutect2
- MNAT1 | c.369G>C p.E123D | Missense Mutation (SNP) | VAF 91/195 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MTNR1B | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 22/419 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.056); called by muse, mutect2
- NIM1K | c.1271G>A p.R424K | Missense Mutation (SNP) | VAF 116/276 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIK3CG | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 168/401 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PLA2G7 | c.901C>G p.P301A | Missense Mutation (SNP) | VAF 113/232 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAB11FIP3 | c.1863G>A p.L621= | Splice Region (SNP) | VAF 174/372 reads (47%) | called by muse, mutect2, varscan2
- SAE1 | c.421_422insCCT p.K141delinsT* | Nonsense Mutation (INS) | VAF 125/286 reads (44%) | called by mutect2, pindel, varscan2
- TRBJ2-5 | c.1_2del p.Q2Rfs*? | Frame Shift Del (DEL) | VAF 217/569 reads (38%) | called by mutect2, pindel, varscan2
- VPS45 | c.263G>C p.R88T | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF133 | c.401C>T p.S134F (on ENST00000316358 / NM_001352454.2; = p.S133F on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/448 reads (3%) | SIFT tolerated (0.43); PolyPhen benign (0.11); called by muse, mutect2
- ZNF658 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 103/293 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EYA1 | c.1449G>A p.L483= | Silent (SNP) | VAF 155/290 reads (53%) | catalogued as COSV58159920; called by muse, mutect2, varscan2
- OR4C3 | c.630C>T p.L210= | Silent (SNP) | VAF 185/373 reads (50%) | catalogued as rs745894531; called by muse, mutect2, varscan2
- PTPN23 | c.3360C>G p.L1120= | Silent (SNP) | VAF 33/955 reads (3%) | called by muse, mutect2
- PTPRJ | c.2175C>T p.F725= | Silent (SNP) | VAF 113/251 reads (45%) | catalogued as rs770495585; called by muse, mutect2, varscan2
- RBM6 | c.2013G>A p.V671= | Silent (SNP) | VAF 146/310 reads (47%) | catalogued as rs1437738843, COSV56487364; called by muse, mutect2, varscan2
- SLITRK2 | c.753G>A p.G251= | Silent (SNP) | VAF 23/281 reads (8%) | called by muse, mutect2
- SUN1 | c.1074G>A p.L358= (on ENST00000405266 / NM_001367651.1; = p.L238= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 35/346 reads (10%) | catalogued as COSV61778235; called by muse, mutect2, varscan2
- ZNF169 | c.1704G>A p.K568= | Silent (SNP) | VAF 194/394 reads (49%) | called by muse, mutect2, varscan2
- DST | c.4297-4984C>T | Intron (SNP) | VAF 95/211 reads (45%) | catalogued as rs894135131; called by muse, mutect2, varscan2
- IGKV1D-16 | chr2:90100738 ins CCG | 3'Flank (INS) | VAF 96/103 reads (93%) | called by mutect2, pindel, varscan2
